Somatic mutation profile of tumor specimen 0DVXFG from CCDI case PBCNIC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 5.2 years (1,899 days).
Specimen 0DVXFG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0044c521-6611-4bd1-a48b-e3f506d3aa49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVXFR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee4f0b0e-38af-4b7a-9d70-9d2a10b5c4e3

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRG1 | c.1366G>A p.V456M (on ENST00000405005 / NM_013964.5; = p.V461M on NM_013956.5) | Missense Mutation (SNP) | VAF 39/834 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs373628055; called by muse, mutect2
